Surgical pathology report (de-identified scan), TCGA case TCGA-75-6212, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-75-6212-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

A description for each data field can be found in the 'Data description' worksheet (yellow tab).

Sample Collection Details							Histology and staging					
Sample Number	Sample Type	Sample Preparation	Site of Tissue	Year of Sample Collection	Age at Sample Collection (yrs)	Sample Comments	Days to Procedure	Days to Diagnosis	Type of Procedure	Site of Primary (Histology)	Tumour Size (cm)	Histology
[REDACTED]	TUMOUR	FF	LLL	[REDACTED]	[REDACTED]		[REDACTED]	[REDACTED]	RESECT	LLL	3.90	03
[REDACTED]	[REDACTED]	FF		[REDACTED]	[REDACTED]		[REDACTED]	[REDACTED]	RESECT	LLL	3.90	03

[page 2 of 2]
Grade/ Differentiation	Pathological T	Pathological N	Clinical M	VALCSG Stage	Histology Comments	Slide URL					
II	T2,NOS	N1	M0		Adenocarcinoma, micropapillary type						
II	T2,NOS	N1	M0		Adenocarcinoma, micropapillary type						

Source: NCI Genomic Data Commons file 66236659-bedc-4c0e-bbda-6314affb5f7a (TCGA-75-6212.6749D901-D37C-4EF9-B0A0-0EE0EE1D7F0E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).